Somatic mutation profile of tumor specimen MP2PRT-PATJPT-TMP1-A (aliquot MP2PRT-PATJPT-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATJPT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (689 days).
Specimen MP2PRT-PATJPT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe17b917-b36b-4d29-a8af-77afd789ccd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJPT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJPT-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/becfcbb2-dfca-4ae0-821a-cef14778b971

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 106/253 reads (42%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CREBBP | c.4420T>C p.C1474R | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52128214; called by muse, mutect2, varscan2
- DPPA5 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 60/656 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs1462976045, COSV64875424; called by muse, mutect2
- GOPC | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 76/786 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV99270943; called by muse, mutect2
- GRIPAP1 | c.1390G>C p.G464R | Missense Mutation (SNP) | VAF 272/1063 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs782173225, COSV100904329; called by muse, mutect2, varscan2
- PSPN | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 102/752 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as rs147164188; called by muse, varscan2
- TBC1D7 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 21/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58243490, COSV58243522; called by muse, mutect2
- CTAGE1 | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HARS2 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2
- TACC2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ADGRV1 | c.5898G>A p.T1966= | Silent (SNP) | VAF 50/350 reads (14%) | catalogued as rs754110689, COSV101315281; called by muse, mutect2, varscan2
- COL9A1 | c.717G>A p.L239= | Silent (SNP) | VAF 60/572 reads (10%) | catalogued as rs767267828; called by muse, mutect2
- MINAR1 | c.1353A>C p.P451= | Silent (SNP) | VAF 66/458 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.15843C>T p.T5281= | Silent (SNP) | VAF 49/514 reads (10%) | catalogued as rs1252368174; called by muse, mutect2
- SPATA8 | n.774T>A | RNA (SNP) | VAF 145/378 reads (38%) | called by muse, mutect2, varscan2
